Somatic mutation profile of tumor specimen TCGA-DD-AACN-01A (aliquot TCGA-DD-AACN-01A-11D-A40R-10) from TCGA case TCGA-DD-AACN, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 32.9 years (12,007 days).
Specimen TCGA-DD-AACN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 300caf8a-f2d8-448d-957f-74cc2166ea48.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AACN-10A (Blood Derived Normal), aliquot TCGA-DD-AACN-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ffbfe942-b914-40f4-b28a-cc7b6096da89

The open-access MAF lists 50 somatic variants for this specimen: 41 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 34, Silent 9, Frame Shift Del 3, Splice Site 2, Translation Start Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM18 | c.268-2A>T p.X90_splice | Splice Site (SNP) | VAF 40/66 reads (61%) | catalogued as COSV99695398; called by muse, mutect2, varscan2
- ADGRV1 | c.17831T>C p.M5944T | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101315786; called by muse, mutect2, varscan2
- ALB | c.250G>C p.E84Q | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as CM900420; called by mutect2, varscan2
- AMER3 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs760195858, COSV58466344; called by muse, mutect2, varscan2
- ARMC7 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99822623; called by muse, mutect2, varscan2
- ATP10D | c.2675C>T p.T892I | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99905519; called by muse, mutect2
- ATP8A1 | c.1832T>C p.V611A | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV100045802; called by muse, mutect2, varscan2
- BORA | c.1822C>G p.Q608E (on ENST00000613797; = p.Q533E on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/191 reads (58%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.281); catalogued as COSV100899869; called by muse, mutect2, varscan2
- BRD7 | c.757del p.T253Lfs*59 | Frame Shift Del (DEL) | VAF 25/61 reads (41%) | catalogued as COSV101164883; called by pindel, varscan2
- CCT5 | c.14G>T p.G5V | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV99725271; called by muse, mutect2, varscan2
- CILP2 | c.1112G>A p.G371D | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.158); catalogued as rs541629092, COSV99364599; called by muse, mutect2, varscan2
- CRB1 | c.1468G>T p.G490C | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV100957823; called by muse, mutect2, varscan2
- CYP2E1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99428937; called by muse, mutect2, varscan2
- EFR3A | c.2104A>G p.T702A | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.203); catalogued as COSV99602850; called by muse, mutect2, varscan2
- INA | c.536G>T p.R179L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100878611; called by muse, mutect2
- ITGA2 | c.2284C>A p.L762M | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.976); catalogued as COSV99670630; called by muse, mutect2, varscan2
- JAKMIP1 | c.2240G>A p.G747D | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.147); catalogued as COSV101290885; called by muse, mutect2, varscan2
- LAMB3 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 119/186 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100620268; called by muse, mutect2, varscan2
- LCAT | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV99863020; called by muse, mutect2, varscan2
- MATK | c.647C>G p.T216S (on ENST00000310132 / NM_139355.3; = p.T217S on NM_002378.4) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.011); catalogued as COSV100036024; called by muse, mutect2, varscan2
- NEBL | c.1450-1G>A p.X484_splice | Splice Site (SNP) | VAF 16/63 reads (25%) | catalogued as rs750724612, COSV101009180; called by muse, mutect2, varscan2
- OLFM3 | c.511A>G p.T171A (on ENST00000338858 / NM_001288821.1; = p.T151A on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 119/187 reads (64%) | SIFT tolerated (0.75); PolyPhen benign (0.011); catalogued as COSV100129281; called by muse, mutect2, varscan2
- P2RY12 | c.567A>G p.I189M | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV99852661; called by muse, mutect2, varscan2
- PACSIN3 | c.563T>A p.L188Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV100096236; called by muse, mutect2, varscan2
- POU2F3 | c.604C>T p.R202C | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765706119, COSV99501005; called by muse, mutect2
- PROSER2 | c.904G>A p.A302T | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs953559219, COSV99508842; called by muse, mutect2, varscan2
- PTPRH | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.036); catalogued as COSV99670946; called by muse, mutect2
- REEP5 | c.230G>A p.S77N | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV99809654; called by muse, mutect2, varscan2
- RETREG1 | c.955T>A p.F319I (on ENST00000306320 / NM_001034850.2; = p.F178I on NM_019000.4) | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100104217; called by muse, mutect2, varscan2
- RPL8 | c.472A>T p.I158F | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as COSV99369848; called by muse, mutect2, varscan2
- TENM2 | c.926G>A p.S309N (on ENST00000518659 / NM_001122679.2; = p.S118N on NM_001080428.3) | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.381); catalogued as rs774385916, COSV101318529; called by muse, mutect2, varscan2
- TMEM30A | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.59); catalogued as rs897424181, COSV100034853; called by muse, mutect2, varscan2
- TTC14 | c.1002G>C p.L334F | Missense Mutation (SNP) | VAF 64/176 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99931987, COSV99932032, COSV99932070; called by muse, mutect2, varscan2
- TYR | c.1466C>T p.T489I | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.074); catalogued as COSV54481224, COSV99633931; called by muse, mutect2, varscan2
- UNC5C | c.1261G>A p.G421R | Missense Mutation (SNP) | VAF 94/183 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1256744960, COSV101497869; called by muse, mutect2, varscan2
- WSB2 | c.551A>G p.N184S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV100199290; called by muse, mutect2, varscan2
- ZNF549 | c.290G>T p.G97V (on ENST00000376233 / NM_001199295.2; = p.G84V on NM_153263.2) | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.023); catalogued as COSV99558495; called by muse, varscan2
- ZSWIM4 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV99584787; called by muse, mutect2, varscan2
- ALB | c.249del p.E84Kfs*57 | Frame Shift Del (DEL) | VAF 20/38 reads (53%) | called by mutect2, varscan2
- KRT40 | c.1217del p.S406* | Frame Shift Del (DEL) | VAF 14/105 reads (13%) | called by mutect2, pindel, varscan2
- ZNF526 | c.319C>T p.P107S | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.397); called by muse, mutect2
- C16orf78 | c.144T>A p.A48= | Silent (SNP) | VAF 35/58 reads (60%) | catalogued as COSV100147663; called by muse, mutect2, varscan2
- KCNT1 | c.1773G>T p.P591= (on ENST00000488444; = p.P610= on NM_020822.3) | Silent (SNP) | VAF 38/192 reads (20%) | catalogued as COSV99705597; called by muse, mutect2, varscan2
- KCNT2 | c.1110A>G p.L370= | Silent (SNP) | VAF 55/202 reads (27%) | catalogued as rs768992345, COSV54081471, COSV99653150; called by muse, mutect2, varscan2
- KIT | c.846T>C p.V282= | Silent (SNP) | VAF 85/136 reads (63%) | catalogued as COSV55390938, COSV99853975; called by muse, mutect2, varscan2
- PRSS16 | c.1542C>A p.V514= | Silent (SNP) | VAF 50/170 reads (29%) | catalogued as COSV100041692; called by muse, mutect2, varscan2
- PTPRD | c.4701T>C p.D1567= | Silent (SNP) | VAF 35/82 reads (43%) | catalogued as COSV100644379; called by muse, mutect2, varscan2
- SNTB2 | c.1251C>T p.F417= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV100293072; called by muse, mutect2, varscan2
- TDRD10 | c.723G>A p.E241= | Silent (SNP) | VAF 42/316 reads (13%) | catalogued as COSV99427389; called by muse, mutect2, varscan2
- ZNF799 | c.1113G>T p.G371= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV101345254; called by muse, mutect2
